Somatic mutation profile of tumor specimen TCGA-77-8009-01A (aliquot TCGA-77-8009-01A-11D-2184-08) from TCGA case TCGA-77-8009, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 68.5 years (25,037 days).
Specimen TCGA-77-8009-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d0739c2-88cd-4e73-874c-7f2e8efee5c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-8009-11A (Solid Tissue Normal), aliquot TCGA-77-8009-11A-01D-2184-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24892aed-494d-4f6a-a681-5368dcb4fd90

The open-access MAF lists 172 somatic variants for this specimen: 134 protein-altering or splice-affecting, 31 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Silent 31, Frame Shift Del 6, Nonsense Mutation 5, Splice Site 4, Intron 4, 3'UTR 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2ML1 | c.1946T>C p.M649T | Missense Mutation (SNP) | VAF 132/297 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100229365; called by muse, mutect2, varscan2
- ACSS3 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs759930604, COSV54098822; called by muse, mutect2, varscan2
- ADAM20 | c.1348G>A p.G450R | Missense Mutation (SNP) | VAF 107/125 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99833557; called by muse, mutect2, varscan2
- ADGRA3 | c.950G>C p.G317A | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.949); catalogued as COSV99293731; called by muse, mutect2, varscan2
- ALDH1A3 | c.342G>T p.L114F | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100320678; called by muse, mutect2, varscan2
- ALDH9A1 | c.1129G>T p.V377L | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs754258086, COSV100699322; called by muse, mutect2, varscan2
- AMOTL1 | c.2634G>C p.Q878H | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100504692; called by muse, varscan2
- AMPH | c.1088T>G p.V363G | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV100343398; called by muse, mutect2, varscan2
- ANKRD17 | c.4361A>G p.K1454R | Missense Mutation (SNP) | VAF 103/132 reads (78%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.607); catalogued as COSV100429871; called by muse, mutect2, varscan2
- ANKRD30A | c.3136G>A p.E1046K (on ENST00000611781; = p.E990K on NM_052997.2) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as COSV64623179; called by muse, mutect2, varscan2
- ANO5 | c.2170G>T p.A724S | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100202168; called by muse, mutect2, varscan2
- ATP11B | c.2380C>T p.R794C | Missense Mutation (SNP) | VAF 30/496 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs995122602, COSV60028906; called by muse, mutect2
- ATP6V0A2 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745357777, COSV100376825; called by muse, mutect2, varscan2
- BRINP1 | c.598G>T p.G200W | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99776705; called by muse, mutect2, varscan2
- C12orf4 | c.1016A>G p.Y339C | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV99712897; called by muse, mutect2, varscan2
- C12orf66 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 23/251 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); catalogued as rs1377065647, COSV61322974; called by muse, mutect2
- C6orf118 | c.997C>A p.L333I | Missense Mutation (SNP) | VAF 42/57 reads (74%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as COSV100025014; called by muse, mutect2, varscan2
- CACUL1 | c.935T>A p.I312N | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100432684; called by muse, mutect2, varscan2
- CAMSAP2 | c.957A>G p.I319M (on ENST00000236925 / NM_001297707.2; = p.I308M on NM_203459.3) | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV99374193; called by muse, mutect2, varscan2
- CBLN2 | c.300C>A p.S100R | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.589); catalogued as COSV99504596; called by muse, mutect2, varscan2
- CCDC47 | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV99854302; called by muse, mutect2, varscan2
- CDH10 | c.54T>A p.H18Q | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100052887; called by muse, mutect2, varscan2
- CDH7 | c.2201del p.A734Vfs*15 | Frame Shift Del (DEL) | VAF 13/106 reads (12%) | catalogued as COSV59886418, COSV59887407; called by mutect2, pindel, varscan2
- CEP72 | c.1261G>T p.A421S | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.059); catalogued as COSV99375251; called by muse, mutect2, varscan2
- CFAP251 | c.3329C>G p.S1110C | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV99996429; called by muse, mutect2, varscan2
- CHMP5 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99794651; called by muse, mutect2, varscan2
- CNTN5 | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 57/88 reads (65%) | catalogued as COSV54304334; called by muse, mutect2, varscan2
- CSF2 | c.358T>C p.F120L | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV99735806; called by muse, mutect2, varscan2
- DIAPH3 | c.2554G>A p.A852T (on ENST00000400324 / NM_001042517.2; = p.A589T on NM_030932.3) | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.955); catalogued as COSV99934366; called by muse, mutect2, varscan2
- DPP10 | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100071042; called by muse, mutect2, varscan2
- DPP4 | c.647G>T p.W216L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100859037; called by muse, mutect2
- DRAM1 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV99315480; called by muse, mutect2
- DSCAM | c.1108C>T p.L370F | Missense Mutation (SNP) | VAF 42/289 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV101261396; called by muse, mutect2, varscan2
- DSG3 | c.2813C>T p.S938L | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV99934643; called by muse, mutect2, varscan2
- DUSP22 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as rs1472941098, COSV60525458; called by muse, mutect2, varscan2
- EBF2 | c.208G>C p.V70L | Missense Mutation (SNP) | VAF 38/48 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0.408); catalogued as COSV101282277, COSV68777405; called by muse, varscan2
- EGR4 | c.1479C>G p.S493R (on ENST00000545030; = p.S390R on NM_001965.4) | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV101474266; called by muse, mutect2, varscan2
- ELAVL2 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV56369783, COSV99807030; called by muse, mutect2, varscan2
- EMB | c.626A>C p.K209T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV100296988; called by muse, mutect2, varscan2
- EXOC3L1 | c.1744G>A p.V582I | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.138); catalogued as COSV99333910; called by muse, mutect2
- FAM102A | c.121G>C p.G41R | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100905380; called by muse, mutect2, varscan2
- FBXL4 | c.1454A>G p.D485G | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV100014347; called by muse, mutect2
- FLOT2 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs771534345, COSV101204803; called by muse, mutect2, varscan2
- FOXK1 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0.01); catalogued as COSV100195735; called by muse, mutect2, varscan2
- GMPS | c.140A>T p.E47V | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99903343; called by muse, mutect2
- GRAMD1C | c.857A>C p.K286T | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.343); catalogued as COSV100822974; called by muse, mutect2, varscan2
- HDAC10 | c.557A>G p.D186G | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99299639; called by muse, mutect2, varscan2
- HKDC1 | c.2335G>A p.G779S | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV100664744; called by muse, mutect2, varscan2
- IFIH1 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.081); catalogued as rs556917411, COSV99718841; called by muse, mutect2, varscan2
- IFNAR2 | c.1003G>A p.G335S | Missense Mutation (SNP) | VAF 74/117 reads (63%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.881); catalogued as rs761802313, COSV51613980; called by muse, mutect2, varscan2
- ILF3 | c.1780C>T p.L594F | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.212); catalogued as COSV99140167; called by muse, mutect2
- KCNT1 | c.275C>T p.S92L (on ENST00000488444; = p.S111L on NM_020822.3) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV99706537; called by muse, mutect2, varscan2
- KCTD16 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV101568866; called by muse, mutect2, varscan2
- KEAP1 | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 275/344 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV50263782, COSV50281859; called by muse, mutect2, varscan2
- KIAA0100 | c.6680A>C p.K2227T | Missense Mutation (SNP) | VAF 205/566 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99972281; called by muse, mutect2, varscan2
- KLHL4 | c.785T>A p.L262Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100910120; called by muse, mutect2, varscan2
- KRT20 | c.424G>T p.V142F | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); catalogued as COSV99391569; called by muse, mutect2, varscan2
- LRGUK | c.2180G>A p.G727E | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs754325149, COSV99604612; called by muse, mutect2, varscan2
- LRRC14B | c.985del p.H329Tfs*34 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as COSV52043098; called by mutect2, pindel, varscan2
- LY9 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV99627370; called by muse, mutect2, varscan2
- MAML1 | c.593T>A p.L198* | Nonsense Mutation (SNP) | VAF 39/81 reads (48%) | catalogued as COSV99483342; called by muse, mutect2, varscan2
- MEGF8 | c.5525T>C p.V1842A (on ENST00000251268 / NM_001271938.2; = p.V1775A on NM_001410.3) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV99238687; called by muse, mutect2
- MEIS1 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 32/505 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760299731, COSV99715710; called by muse, mutect2
- MEOX2 | c.720G>T p.M240I | Missense Mutation (SNP) | VAF 65/135 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100012469, COSV56289958; called by muse, mutect2, varscan2
- MMP25 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV100339594; called by muse, mutect2
- MSMO1 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99823405; called by muse, mutect2, varscan2
- MTRR | c.55A>G p.S19G | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as COSV52946140, COSV99242031; called by muse, mutect2, varscan2
- MTUS2 | c.1721C>G p.P574R | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs762222069, COSV101462348, COSV70912557; called by muse, mutect2, varscan2
- MUC16 | c.28166C>T p.T9389I | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.943); catalogued as COSV101201306; called by muse, mutect2
- MYF5 | c.141G>T p.Q47H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.478); catalogued as COSV99953383; called by muse, mutect2, varscan2
- MYOM1 | c.614C>G p.S205C | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.52); catalogued as COSV55289008, COSV99868098; called by muse, mutect2, varscan2
- NAP1L1 | c.441A>T p.K147N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.411); catalogued as COSV99674035; called by muse, mutect2, varscan2
- NCAM2 | c.1480G>T p.D494Y | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99524944; called by muse, mutect2, varscan2
- NR3C2 | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as rs1220830173, COSV100679680; called by muse, mutect2
- OPCML | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV100104422; called by muse, mutect2, varscan2
- OR4C46 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100060944; called by muse, mutect2, varscan2
- PARD3B | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV100594963; called by muse, mutect2, varscan2
- PBDC1 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV100972859; called by muse, mutect2
- PCDH15 | c.481C>A p.P161T | Missense Mutation (SNP) | VAF 57/72 reads (79%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100226578, COSV57302735; called by muse, mutect2, varscan2
- PCDHB12 | c.1453C>A p.Q485K | Missense Mutation (SNP) | VAF 52/215 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.22); catalogued as COSV99507741; called by muse, mutect2, varscan2
- PCDHGA6 | c.1237del p.E413Kfs*10 | Frame Shift Del (DEL) | VAF 12/110 reads (11%) | catalogued as COSV53965275; called by mutect2, pindel, varscan2
- PCDHGB2 | c.944A>G p.Y315C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99545628; called by muse, mutect2, varscan2
- PDE5A | c.2407G>A p.D803N | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as COSV99309134; called by muse, mutect2
- PDZRN4 | c.1930G>A p.D644N (on ENST00000402685 / NM_001164595.2; = p.D386N on NM_013377.4) | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.91); catalogued as COSV100115350; called by muse, mutect2
- PEG3 | c.239G>C p.R80P | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV99690179; called by muse, mutect2, varscan2
- PIFO | c.241T>C p.F81L | Missense Mutation (SNP) | VAF 46/61 reads (75%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV100868639; called by muse, mutect2, varscan2
- PIK3C2A | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99791142; called by muse, mutect2, varscan2
- PIK3R1 | c.1020-2A>C p.X340_splice (on ENST00000521381 / NM_181523.3; = p.X70_splice on NM_181504.4) | Splice Site (SNP) | VAF 31/47 reads (66%) | catalogued as COSV99151391; called by muse, mutect2, varscan2
- PLK4 | c.1229G>A p.R410K | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV99584911; called by muse, mutect2, varscan2
- PNLIP | c.1201A>C p.N401H | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV100981951; called by muse, mutect2, varscan2
- POU6F2 | c.1612G>T p.A538S | Missense Mutation (SNP) | VAF 168/369 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.061); catalogued as COSV101302830; called by muse, mutect2, varscan2
- PRDM9 | c.1570G>T p.V524F | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV99691114; called by muse, mutect2, varscan2
- PRKCSH | c.1070C>G p.P357R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770401000, COSV99371903; called by muse, varscan2
- PTPN7 | c.383T>A p.I128N (on ENST00000495688; = p.I167N on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749448516, COSV100460094; called by muse, mutect2, varscan2
- RGS7 | c.549G>T p.K183N | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100467169, COSV58565566; called by muse, mutect2, varscan2
- RHBG | c.220G>T p.G74C | Missense Mutation (SNP) | VAF 136/255 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99660022; called by muse, mutect2
- RNF103 | c.1545G>T p.W515C | Missense Mutation (SNP) | VAF 128/319 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99410368; called by muse, mutect2, varscan2
- RRP1B | c.1885A>G p.S629G | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100513208; called by muse, mutect2, varscan2
- SCN7A | c.738T>A p.F246L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV101313347; called by muse, mutect2, varscan2
- SLC24A3 | c.863G>T p.S288I | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV100042785; called by muse, mutect2, varscan2
- SLC38A9 | c.1167+1G>T p.X389_splice | Splice Site (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100591557; called by muse, mutect2
- SPDEF | c.829+1G>A p.X277_splice | Splice Site (SNP) | VAF 109/140 reads (78%) | catalogued as COSV99763310; called by muse, mutect2, varscan2
- SRPX2 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100884059; called by muse, mutect2
- STK17B | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99826285; called by muse, mutect2, varscan2
- SULT1E1 | c.818A>G p.E273G | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99895202; called by muse, mutect2, varscan2
- SUN1 | c.2111A>G p.N704S (on ENST00000405266 / NM_001367651.1; = p.N584S on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/358 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV101273064; called by muse, mutect2
- TBC1D12 | c.1675T>C p.Y559H | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.722); catalogued as rs1288579988, COSV99831751; called by muse, mutect2, varscan2
- TBC1D12 | c.1676A>T p.Y559F | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV99831753; called by muse, mutect2, varscan2
- TMEM198 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 56/66 reads (85%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV99525488; called by muse, mutect2, varscan2
- TOX | c.1336G>T p.G446W | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100789295; called by muse, mutect2, varscan2
- TRAF6 | c.630G>T p.L210F | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as COSV100777736; called by muse, mutect2, varscan2
- TRIM3 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs756669130, COSV100624530; called by muse, mutect2, varscan2
- TRMT10A | c.811A>G p.I271V | Missense Mutation (SNP) | VAF 80/94 reads (85%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs768659818, COSV99911036; called by muse, mutect2, varscan2
- TTN | c.95156C>T p.A31719V (on ENST00000591111; = p.A24295V on NM_003319.4) | Missense Mutation (SNP) | VAF 25/56 reads (45%) | PolyPhen possibly damaging (0.864); catalogued as COSV60330169; called by muse, mutect2, varscan2
- TTN | c.71954T>C p.L23985S (on ENST00000591111; = p.L16561S on NM_003319.4) | Missense Mutation (SNP) | VAF 132/291 reads (45%) | PolyPhen benign (0.113); catalogued as COSV100626944; called by muse, mutect2, varscan2
- TUBGCP6 | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 29/311 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759505934, COSV50547526, COSV50572772; called by muse, mutect2, varscan2
- UNC79 | c.4720C>T p.R1574* (on ENST00000393151 / NM_001346218.2; = p.R1397* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 65/114 reads (57%) | catalogued as COSV99829639; called by muse, mutect2, varscan2
- UTP3 | c.737C>G p.P246R | Missense Mutation (SNP) | VAF 35/46 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99637122; called by muse, mutect2, varscan2
- VPS29 | c.262C>T p.H88Y | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV100804913; called by muse, mutect2, varscan2
- ZFPM2 | c.655T>C p.Y219H | Missense Mutation (SNP) | VAF 83/118 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101023483, COSV65873389; called by muse, mutect2, varscan2
- ZIC4 | c.502C>G p.Q168E | Missense Mutation (SNP) | VAF 176/273 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.741); catalogued as COSV101268129; called by muse, mutect2, varscan2
- ZNF160 | c.2086C>T p.Q696* | Nonsense Mutation (SNP) | VAF 18/196 reads (9%) | catalogued as COSV100762460, COSV61999332; called by muse, mutect2
- ZNF385B | c.833C>A p.S278Y | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV100416387; called by muse, varscan2
- ZNF480 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.815); catalogued as COSV57995106; called by muse, mutect2
- ZNF524 | c.19G>C p.D7H | Missense Mutation (SNP) | VAF 79/173 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.732); catalogued as COSV99684719; called by muse, mutect2, varscan2
- CNTN3 | c.1819dup p.D607Gfs*2 | Frame Shift Ins (INS) | VAF 34/78 reads (44%) | called by mutect2, pindel, varscan2
- HRH4 | c.826del p.M276Wfs*10 | Frame Shift Del (DEL) | VAF 93/251 reads (37%) | called by mutect2, pindel, varscan2
- IGHV4-34 | c.260C>A p.P87Q | Missense Mutation (SNP) | VAF 83/147 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- KRTAP13-3 | c.221G>T p.S74I | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- OGDH | c.2313del p.Q772Rfs*83 | Frame Shift Del (DEL) | VAF 59/189 reads (31%) | called by mutect2, pindel, varscan2
- PALM2AKAP2 | c.259_272del p.V87Pfs*13 (on ENST00000259318 / NM_001136562.3; = p.V318Pfs*13 on NM_007203.5) | Frame Shift Del (DEL) | VAF 17/94 reads (18%) | called by mutect2, pindel
- RP1 | c.3664_3665insGG p.K1222Rfs*34 | Frame Shift Ins (INS) | VAF 13/110 reads (12%) | called by mutect2, pindel*, varscan2
- TRBV20-1 | c.112C>A p.R38S | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- WWC3 | c.507+2_507+8del p.X169_splice | Splice Site (DEL) | VAF 14/52 reads (27%) | called by mutect2, pindel, varscan2
- ACSL6 | c.1080C>T p.P360= (on ENST00000379240; = p.P385= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as rs780761195, COSV99734513; called by muse, mutect2, varscan2
- ACTR2 | c.489G>A p.V163= | Silent (SNP) | VAF 50/425 reads (12%) | catalogued as COSV99574101; called by muse, varscan2
- ADGRG5 | c.207G>A p.Q69= | Silent (SNP) | VAF 79/184 reads (43%) | catalogued as rs373289339; called by muse, mutect2, varscan2
- ANK1 | c.504C>G p.T168= | Silent (SNP) | VAF 25/35 reads (71%) | catalogued as rs1259031440, COSV99226611; called by muse, mutect2, varscan2
- CDK13 | c.2148C>T p.Y716= | Silent (SNP) | VAF 49/183 reads (27%) | catalogued as rs151007323; called by muse, mutect2, varscan2
- CEP72 | c.1260G>T p.A420= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV99375249; called by muse, mutect2, varscan2
- CHAC1 | c.39C>A p.T13= | Silent (SNP) | VAF 50/63 reads (79%) | catalogued as COSV101471079; called by muse, mutect2, varscan2
- CNTN6 | c.1731C>T p.C577= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs1183250270, COSV100611724; called by muse, mutect2, varscan2
- COL5A1 | c.1479G>T p.G493= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as COSV100880510; called by muse, mutect2, varscan2
- COLGALT1 | c.1233C>T p.G411= | Silent (SNP) | VAF 11/126 reads (9%) | catalogued as COSV99395251; called by muse, mutect2
- EFCAB6 | c.2979G>A p.L993= | Silent (SNP) | VAF 42/144 reads (29%) | catalogued as rs748596351, COSV99414264; called by muse, mutect2, varscan2
- FLG | c.10485A>G p.S3495= | Silent (SNP) | VAF 159/636 reads (25%) | catalogued as COSV100912038; called by muse, mutect2, varscan2
- IGSF3 | c.2685T>C p.S895= (on ENST00000369486 / NM_001007237.3; = p.S915= on NM_001542.4) | Silent (SNP) | VAF 4/53 reads (8%) | catalogued as COSV100605053; called by muse, mutect2
- KCNE4 | c.249T>C p.N83= | Silent (SNP) | VAF 72/91 reads (79%) | catalogued as COSV99919093; called by muse, mutect2, varscan2
- KHDRBS3 | c.252G>A p.L84= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as COSV100878986; called by muse, mutect2
- MNDA | c.585G>A p.Q195= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV63739854, COSV63740454; called by muse, mutect2, varscan2
- MYL6 | c.159G>A p.G53= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV52879436; called by muse, mutect2, varscan2
- OR2M4 | c.321G>A p.L107= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs753878200, COSV100141480; called by muse, mutect2, varscan2
- PCDHA5 | c.1143C>T p.N381= | Silent (SNP) | VAF 22/175 reads (13%) | catalogued as COSV100972457; called by muse, mutect2, varscan2
- PDK2 | c.345C>T p.A115= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV99142937, COSV99143078; called by muse, mutect2, varscan2
- POU3F4 | c.618C>T p.I206= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV100937320, COSV64538812; called by muse, mutect2
- RBMY1E | c.1308G>T p.S436= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV100740356; called by mutect2, varscan2
- RPRD2 | c.1254A>G p.P418= | Silent (SNP) | VAF 54/79 reads (68%) | catalogued as rs781879488, COSV64822911; called by muse, mutect2, varscan2
- SERTAD2 | c.264C>G p.P88= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as COSV100512274; called by muse, mutect2, varscan2
- SLC3A1 | c.1437C>T p.Y479= | Silent (SNP) | VAF 54/94 reads (57%) | catalogued as rs200007474, COSV99576898, COSV99577556; called by muse, mutect2, varscan2
- SLC9A8 | c.339G>A p.A113= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as rs773532739, COSV64287715; called by muse, mutect2, varscan2
- TMEM132B | c.1335C>G p.V445= | Silent (SNP) | VAF 91/285 reads (32%) | catalogued as COSV100170721; called by muse, mutect2, varscan2
- TRAM1L1 | c.1089G>A p.K363= | Silent (SNP) | VAF 19/132 reads (14%) | catalogued as COSV100162337; called by muse, mutect2, varscan2
- TRIM14 | c.27G>A p.R9= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV100419706; called by muse, mutect2, varscan2
- UNC5D | c.472C>A p.R158= | Silent (SNP) | VAF 64/84 reads (76%) | catalogued as COSV54846900, COSV99778300; called by muse, mutect2, varscan2
- ZNF548 | c.654C>T p.I218= | Silent (SNP) | VAF 5/98 reads (5%) | catalogued as COSV100278275; called by muse, mutect2
- CRYGS | c.*1T>G | 3'UTR (SNP) | VAF 28/338 reads (8%) | catalogued as COSV100330054; called by muse, mutect2
- CSH1 | c.456+17G>A | Intron (SNP) | VAF 80/151 reads (53%) | catalogued as rs140138679; called by muse, mutect2, varscan2
- DST | c.4297-1531C>A | Intron (SNP) | VAF 86/139 reads (62%) | catalogued as COSV99759338; called by muse, mutect2, varscan2
- GALP | c.*1A>G | 3'UTR (SNP) | VAF 16/79 reads (20%) | catalogued as COSV100628054; called by muse, mutect2, varscan2
- GP6 | c.*54C>T | 3'UTR (SNP) | VAF 36/103 reads (35%) | catalogued as rs1460585896, COSV100117733; called by muse, mutect2, varscan2
- NRP1 | c.1759+1243G>A | Intron (SNP) | VAF 6/53 reads (11%) | catalogued as COSV99589497; called by muse, mutect2, varscan2
- SYTL2 | c.1460-3102C>T | Intron (SNP) | VAF 18/227 reads (8%) | catalogued as rs750087093, COSV100314829; called by muse, mutect2
